Somatic mutation profile of tumor specimen TARGET-10-PATEIT-09A (aliquot TARGET-10-PATEIT-09A-01D) from TARGET case TARGET-10-PATEIT, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.5 years (3,485 days).
Specimen TARGET-10-PATEIT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a47a1da-66b1-48bb-ab33-2a0a2bc5c11c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATEIT-14A (Bone Marrow Normal), aliquot TARGET-10-PATEIT-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0901be95-0643-4323-b5d8-e68285ea36db

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 8/67 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKRD13A | c.841C>A p.R281S | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55675252, COSV55679096; called by muse, mutect2, varscan2
- EPPK1 | c.4681G>A p.D1561N | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as COSV73262579; called by muse, mutect2, varscan2
- HPS3 | c.1946C>T p.P649L | Missense Mutation (SNP) | VAF 88/155 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56058146, COSV99937433; called by mutect2, varscan2
- METTL25 | c.937T>A p.S313T | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.103); catalogued as COSV50259985; called by muse, mutect2
- OBSCN | c.8984G>A p.R2995Q | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs775338869, COSV52847118, COSV99472892; called by muse, mutect2, varscan2
- PCLO | c.14662G>T p.G4888C | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61620196, COSV61679047; called by muse, mutect2
- PIK3CD | c.371G>A p.G124D | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV63128987; called by muse, mutect2
- RAB3C | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51437659; called by muse, mutect2
- CARS2 | c.952dup p.M318Nfs*12 | Frame Shift Ins (INS) | VAF 26/80 reads (33%) | called by mutect2, varscan2
- RETREG2 | c.468G>T p.E156D | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- BCL9L | c.3369G>A p.L1123= | Silent (SNP) | VAF 18/35 reads (51%) | called by mutect2, varscan2
- PDE6B | c.306C>T p.G102= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as rs201939549, COSV55328837; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSLP | c.72G>A p.G24= | Silent (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2, varscan2
- PRPF4BP1 | n.193G>A | RNA (SNP) | VAF 85/178 reads (48%) | catalogued as rs1365531575; called by muse, mutect2, varscan2
